Somatic mutation profile of tumor specimen TCGA-CZ-4856-01A (aliquot TCGA-CZ-4856-01A-02D-1429-08) from TCGA case TCGA-CZ-4856, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 62.1 years (22,684 days).
Specimen TCGA-CZ-4856-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eaafa2a-7eed-4a79-9e05-1262c7eab417.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-4856-11A (Solid Tissue Normal), aliquot TCGA-CZ-4856-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbac0677-8f0f-4456-9769-894ae97611f2

The open-access MAF lists 66 somatic variants for this specimen: 54 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 40, Silent 12, Frame Shift Del 7, Nonsense Mutation 3, Frame Shift Ins 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.463+2T>C p.X155_splice | Splice Site (SNP) | VAF 47/233 reads (20%) | hotspot (GDC flag); catalogued as rs5030814, CS961707, COSV56543181, COSV56545468, COSV56553134; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- ACAP2 | c.2108C>T p.T703I | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.077); catalogued as COSV58752376; called by muse, mutect2, varscan2
- AGO2 | c.1588G>A p.A530T | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV55048065, COSV99595918; called by muse, mutect2, varscan2
- AGO3 | c.2203A>G p.T735A | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1223902159, COSV55793794; called by muse, mutect2, varscan2
- ANXA6 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); catalogued as rs200516508, COSV100637103; called by muse, mutect2, varscan2
- AP5M1 | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV55105464; called by muse, mutect2, varscan2
- ARL14EP | c.574A>T p.S192C | Missense Mutation (SNP) | VAF 42/221 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV56342920; called by muse, varscan2
- ATP2A1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.099); catalogued as rs770770067, COSV63920624; called by muse, mutect2, varscan2
- BMP5 | c.1292A>T p.Y431F | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV63703579; called by muse, mutect2, varscan2
- C9orf131 | c.1460C>T p.P487L | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56611690; called by muse, mutect2, varscan2
- CIC | c.3543G>C p.K1181N | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV50581440; called by muse, mutect2, varscan2
- COIL | c.323A>T p.K108I | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53595168; called by muse, mutect2
- CR1L | c.717A>G p.I239M | Missense Mutation (SNP) | VAF 24/530 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as COSV54326855; called by muse, mutect2
- CSMD2 | c.8203C>T p.R2735W | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761713162, COSV53917880; called by muse, mutect2, varscan2
- DNAH9 | c.4549C>T p.R1517* | Nonsense Mutation (SNP) | VAF 22/141 reads (16%) | catalogued as rs144649934; called by muse, mutect2, varscan2
- DST | c.19624C>T p.Q6542* (on ENST00000361203 / NM_001374722.1; = p.Q4239* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 35/169 reads (21%) | catalogued as COSV55018174; called by muse, mutect2, varscan2
- F11 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.929); catalogued as rs201688862, CM083501, COSV53007113; ClinVar: uncertain significance; called by muse, mutect2
- FSTL4 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 25/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749369391, COSV54768057; called by muse, mutect2, varscan2
- GGT5 | c.1549A>G p.I517V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV54070469; called by muse, mutect2
- GPRC5A | c.289C>G p.R97G | Missense Mutation (SNP) | VAF 65/444 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50007868; called by muse, mutect2, varscan2
- GRIN2B | c.3017G>C p.C1006S | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.987); catalogued as COSV74206119; called by muse, mutect2
- HIVEP1 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 69/319 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV65102105; called by muse, mutect2, varscan2
- IRAK1BP1 | c.574C>A p.L192I | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV64048295; called by muse, mutect2, varscan2
- KLHL17 | c.586G>T p.G196C | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58532095; called by mutect2, varscan2
- LY6E | c.266G>C p.G89A | Missense Mutation (SNP) | VAF 24/152 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.667); catalogued as COSV52869839; called by muse, mutect2, varscan2
- MARCHF7 | c.113A>G p.H38R | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs768935744, COSV52029083; called by muse, mutect2, varscan2
- MIS18BP1 | c.3302G>A p.G1101E | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV57501900; called by muse, mutect2, varscan2
- OR5P2 | c.370A>T p.S124C | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); catalogued as rs752161438, COSV61490684; called by muse, mutect2
- PCDHGB3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773502490, COSV53960408; called by muse, mutect2, varscan2
- PDE6B | c.1490C>G p.T497S | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV55327051, COSV55328362; called by muse, mutect2, varscan2
- PRKG2 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as rs187350442; called by muse, mutect2, varscan2
- PTPRT | c.1958G>T p.R653L | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV61985408, COSV61985479, COSV62019583; called by muse, mutect2, varscan2
- RPAP1 | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58539575; called by muse, mutect2, varscan2
- RSPRY1 | c.1466T>C p.M489T | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs755216093, COSV68027757; called by muse, mutect2, varscan2
- SETBP1 | c.4144G>A p.A1382T | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.124); catalogued as COSV56324069; called by muse, mutect2, varscan2
- SLC17A5 | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.01); catalogued as COSV63287544; called by muse, mutect2
- SLC35G3 | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 52/243 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs149963193; called by muse, mutect2, varscan2
- SLC44A4 | c.38A>G p.Y13C | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV57667422; called by muse, mutect2
- STON1 | c.1708A>G p.I570V | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.509); catalogued as COSV59131527; called by muse, mutect2
- TDRD9 | c.1451G>T p.W484L | Missense Mutation (SNP) | VAF 17/236 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59148354; called by muse, mutect2
- WDR27 | c.376G>T p.V126L | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV61209722; called by muse, mutect2
- ZMYM4 | c.3651G>A p.W1217* | Nonsense Mutation (SNP) | VAF 12/162 reads (7%) | catalogued as COSV58911413; called by muse, mutect2
- ZNF749 | c.152A>C p.H51P | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.648); catalogued as COSV61946317; called by muse, mutect2, varscan2
- CD1D | c.100_101insG p.S34Cfs*6 | Frame Shift Ins (INS) | VAF 66/428 reads (15%) | called by mutect2, pindel*, varscan2
- CEP290 | c.5622del p.I1874Mfs*11 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | called by mutect2, pindel, varscan2
- DDX19B | c.50del p.A17Vfs*4 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel
- KPRP | c.875del p.P292Lfs*79 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by mutect2, pindel, varscan2
- MCU | c.1054_*1del | Frame Shift Del (DEL) | VAF 23/95 reads (24%) | called by mutect2, pindel, varscan2
- PPP1R3C | c.744del p.N248Kfs*39 | Frame Shift Del (DEL) | VAF 31/147 reads (21%) | called by mutect2, pindel, varscan2
- TAF15 | c.655G>A p.G219R (on ENST00000605844 / NM_139215.3; = p.G216R on NM_003487.4) | Missense Mutation (SNP) | VAF 17/230 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- TMEM245 | c.1184_1185insT p.V396Sfs*43 | Frame Shift Ins (INS) | VAF 24/190 reads (13%) | called by mutect2, varscan2
- TMEM245 | c.1182dup p.G395Wfs*44 | Frame Shift Ins (INS) | VAF 19/209 reads (9%) | called by mutect2*, pindel, varscan2*
- WDR25 | c.224del p.G75Afs*63 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | called by mutect2, pindel, varscan2
- ZNF34 | c.1525_1534del p.K509Sfs*7 | Frame Shift Del (DEL) | VAF 12/127 reads (9%) | called by mutect2, pindel
- APH1B | c.18C>T p.F6= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV56014500; called by muse, varscan2
- ARMCX5 | c.1440A>T p.A480= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as COSV55766756; called by muse, mutect2
- BRPF3 | c.3012A>G p.K1004= | Silent (SNP) | VAF 24/129 reads (19%) | catalogued as COSV60207711; called by muse, mutect2, varscan2
- FNDC3B | c.3162C>T p.P1054= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV61043396; called by muse, mutect2
- GPRASP2 | c.1287C>A p.S429= | Silent (SNP) | VAF 60/264 reads (23%) | catalogued as COSV59991495; called by muse, mutect2, varscan2
- KLHL17 | c.585G>T p.L195= | Silent (SNP) | VAF 13/121 reads (11%) | catalogued as COSV58532084; called by mutect2, varscan2
- LY6E | c.267C>T p.G89= | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as rs756207064, COSV52869854, COSV52870010; called by muse, mutect2, varscan2
- PLA2G4A | c.39G>A p.E13= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs1473721164, COSV66554364; called by muse, mutect2, varscan2
- PTPRT | c.1959G>T p.R653= | Silent (SNP) | VAF 44/182 reads (24%) | catalogued as COSV61985457; called by muse, mutect2, varscan2
- SLC13A5 | c.1332C>T p.P444= | Silent (SNP) | VAF 40/183 reads (22%) | catalogued as COSV53423370; called by muse, mutect2, varscan2
- UCK2 | c.9G>A p.G3= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs759233080; called by muse, varscan2
- ZNF594 | c.849C>A p.V283= | Silent (SNP) | VAF 32/183 reads (17%) | catalogued as COSV68385402; called by muse, mutect2, varscan2
